Somatic mutation profile of tumor specimen HTMCP-03-06-02402-01A (aliquot HTMCP-03-06-02402-01A-01D-10409) from CGCI case HTMCP-03-06-02402, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIA2; Tumor grade: G3.
Specimen HTMCP-03-06-02402-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a6e30952-cd14-45c4-aec6-ce40163e13f5.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02402-10A (Blood Derived Normal), aliquot HTMCP-03-06-02402-10A-01D-10409; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7e29535e-090c-486c-8d10-b3f4e281cd6a

The open-access MAF lists 10 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 6, Silent 3, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAH11 | c.10261G>A p.V3421I | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs770172153; called by mutect2, varscan2
- KCND2 | c.477G>C p.E159D | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58577084; called by muse, mutect2, varscan2
- MACF1 | c.21847G>A p.D7283N (on ENST00000372915; = p.D5328N on NM_012090.5) | Missense Mutation (SNP) | VAF 13/109 reads (12%) | catalogued as rs1163784106, COSV57116983, COSV57146428; called by muse, mutect2, varscan2
- NLGN3 | c.2104C>T p.R702C (on ENST00000358741 / NM_181303.2; = p.R682C on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100704877; called by muse, mutect2
- EPHA2 | c.1876dup p.E626Gfs*68 | Frame Shift Ins (INS) | VAF 6/34 reads (18%) | called by mutect2, pindel, varscan2
- IRS4 | c.1886C>T p.P629L | Missense Mutation (SNP) | VAF 14/240 reads (6%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.006); called by muse, mutect2
- RICTOR | c.1329C>G p.S443R | Missense Mutation (SNP) | VAF 25/142 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- FAM47B | c.1290C>T p.T430= | Silent (SNP) | VAF 21/303 reads (7%) | catalogued as rs1350753109, COSV100264784, COSV61456172; called by muse, mutect2
- KCNT1 | c.2574G>A p.A858= (on ENST00000488444; = p.A877= on NM_020822.3) | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs761157491, COSV53700692; called by mutect2, varscan2
- TBC1D2B | c.2763C>T p.R921= (on ENST00000300584 / NM_144572.1; = p.A904V on NM_015079.6) | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as rs560412956, COSV56044098; called by mutect2, varscan2
